CCDI case PBCDSX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified parts of mouth.
https://portal.gdc.cancer.gov/cases/7fcc0cc5-092c-4509-a6df-e3689dac1347

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Mandible; Age at diagnosis: 5.4 years (1,977 days).

Biospecimens (3 samples)
- Sample 0DPJSC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPJSN, 0DPJT8 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
